Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A85A, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A85A-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Path# [REDACTED]

Accessioned

Birthdate: [REDACTED]

(Age

Loc: [REDACTED]

Gender: M

Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1.2, RIGHT FRONTAL BRAIN TUMOR, BRAIN TUMOR, (BIOPSY):
LOW GRADE ASTROCYTOMA, WHO II/IV. THE KI-67 INDEX IS 5%.
PENDING MOLECULAR STUDIES TO RULE OUT OLIGODENDROGLIOMA.
DR HAS SEEN THIS CASE.

[REDACTED]

* Signed copy on file

ADDENDUM:

NOTE ADDED

NO EVIDENCE OF LOH WAS DETECTED IN 1p OR IN 19q. THE COMPLETE REPORT
IS ON FILE IN THE . THE DIAGNOSIS
REMAINS ASTROCYTOMA, WHO II/IV.

[REDACTED]

*Electronic signature

=====

Pre-Operative Diagnosis:
RIGHT FRONTAL BRAIN TUMOR

GROSS DESCRIPTION

(Continued on next page.)

ICD.O-3

Astrocytoma, grade II 9400/3
Site: ^{cell} Brain, supratentorial NOS C71.0
^{path} Brain, frontal lobe C71.1
J.D 6/10/14

[page 2 of 3]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] #- [REDACTED]

Page 2

PART #1: FS: RIGHT FRONTAL BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / [REDACTED]

- 1) FS: RIGHT FRONTAL BRAIN TUMOR: MODESTLY HYPERCELLULAR GLIAL
TISSUE, CONSISTENT WITH LOW-GRADE GLIOMA.

DIAGNOSIS CONFIRMED WITH [REDACTED] AT .

THE SPECIMEN IS RECEIVED FRESH FOR FROZEN SECTION DIAGNOSIS, LABELED
WITH THE PATIENT'S NAME, [REDACTED], AND DESIGNATED RIGHT FRONTAL
BRAIN TUMOR. THE SPECIMEN CONSISTS OF MULTIPLE FRAGMENTS OF PINK-TAN
SOFT TISSUE MEASURING 2.0 X 1.5 X 0.5 CM IN AGGREGATE. ONE FRAGMENT IS
SUBMITTED FOR FROZEN SECTION. THE REST OF THE SPECIMEN IS SUBMITTED
IN ITS ENTIRETY IN A BIOPSY BAG.

1 -FSC- 1

1 - A - M

2 - T - M

(Continued on next page.)

[page 3 of 3]
Patient: [REDACTED]
[REDACTED] # [REDACTED]

Path# [REDACTED]

Page 3

PART #2: BRAIN TUMOR
Resident Pathologist: [REDACTED]

THE SPECIMEN IS RECEIVED IN SALINE, LABELED WITH THE PATIENT'S NAME, [REDACTED] AND DESIGNATED RIGHT FRONTAL BRAIN TUMOR. THE SPECIMEN CONSISTS OF TWO LARGE FRAGMENTS OF WHITE-TAN-PINK SOFT TISSUE CONSISTENT WITH BRAIN MEASURING 7.0 X 6.5 X 2.0 CM IN AGGREGATE. SECTIONING REVEALS A PALE-TAN-WHITE, SOFT AND GLISTENING CUT SURFACE. ALSO RECEIVED IN THE SPECIMEN CONTAINER ARE MULTIPLE IRREGULAR FRAGMENTS OF SIMILAR TISSUE MEASURING 2.0 X 1.0 X 0.5 CM IN AGGREGATE. REPRESENTATIVE SECTIONS ARE SUBMITTED.

S.O.S.:

5 -A-E- 1 (RT FRONTAL BRAIN TUMOR)
1 - F - M (ADDITIONAL SMALLER TISSUE)
6 - T - M

(End of Report)

printed

Source: NCI Genomic Data Commons file 47109237-8c9c-4422-bd69-430aea99948d (TCGA-WY-A85A.AEC260E5-995F-439A-8042-788A2EEAB136.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).